Somatic mutation profile of tumor specimen ALCH-B3GR-TTP1-A (aliquot ALCH-B3GR-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3GR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.2 years (21,635 days).
Specimen ALCH-B3GR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82efc936-43f2-46a1-b6d3-347a0b7f279a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3GR-NB1-A (Blood Derived Normal), aliquot ALCH-B3GR-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcc50ad2-da7c-41df-aac0-57168b220703

The open-access MAF lists 130 somatic variants for this specimen: 83 protein-altering or splice-affecting, 29 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 29, Intron 6, 3'UTR 5, RNA 3, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, 5'UTR 2, 5'Flank 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 65/272 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSBG1 | c.1533C>A p.D511E | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV99357924; called by muse, mutect2, varscan2
- ARHGAP17 | c.1744C>G p.P582A (on ENST00000289968 / NM_001006634.3; = p.P504A on NM_018054.6) | Missense Mutation (SNP) | VAF 48/425 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV51506911; called by muse, mutect2, varscan2
- ARHGAP33 | c.2002G>T p.G668C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as COSV50121384; called by muse, mutect2, varscan2
- CNKSR2 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1331333378, COSV54261900; called by muse, mutect2, varscan2
- CRIP2 | c.407-4C>G | Splice Region (SNP) | VAF 38/110 reads (35%) | catalogued as rs782666397; called by muse, mutect2, varscan2
- HIVEP2 | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs540360531, COSV50036736; called by muse, mutect2, varscan2
- IREB2 | c.1901C>A p.A634D | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51927579; called by muse, mutect2, varscan2
- KIR3DL1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 76/392 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.413); catalogued as rs952277445; called by muse, varscan2
- LAMA2 | c.2958G>T p.W986C | Missense Mutation (SNP) | VAF 55/510 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as CM151368, COSV70346121; called by muse, mutect2, varscan2
- LRRC7 | c.2357C>T p.P786L (on ENST00000651989 / NM_001370785.2; = p.P753L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs1305758247; called by muse, mutect2, varscan2
- NCAPD3 | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.854); catalogued as COSV73259033; called by muse, mutect2, varscan2
- NLGN3 | c.880G>A p.V294I (on ENST00000358741 / NM_181303.2; = p.V274I on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); catalogued as COSV62444043; called by muse, mutect2, varscan2
- OR10G2 | c.406C>A p.R136S | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs1369449667; called by muse, mutect2, varscan2
- OR4K5 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 64/362 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60003917; called by muse, mutect2, varscan2
- OR52N5 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as COSV57698514; called by muse, mutect2, varscan2
- PCDHB8 | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 86/617 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV50754722, COSV50793442; called by muse, mutect2, varscan2
- RAB11FIP4 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.153); catalogued as rs1029178031; called by muse, mutect2, varscan2
- RBM20 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 63/259 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756116415; called by muse, mutect2, varscan2
- RBMS3 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs756605759; called by muse, mutect2, varscan2
- RYR3 | c.9808C>T p.R3270C (on ENST00000389232; = p.R3271C on NM_001036.6) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200295482, COSV101211811, COSV101213130; called by muse, mutect2, varscan2
- SLC4A10 | c.1654G>T p.G552W (on ENST00000446997 / NM_001354461.2; = p.G522W on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55771511, COSV99765436; called by muse, mutect2, varscan2
- SMAD6 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56595748; called by muse, mutect2, varscan2
- SPATA48 | c.491A>G p.Q164R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs778893172; called by muse, mutect2, varscan2
- SPTBN5 | c.5063C>T p.T1688M | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs375195892; called by muse, mutect2, varscan2
- SV2A | c.1381T>A p.Y461N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV64965848; called by muse, mutect2, varscan2
- TMPRSS11F | c.929A>G p.Q310R | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.988); catalogued as rs765620321; called by muse, mutect2, varscan2
- TUBGCP2 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as rs758587313, COSV53304640; called by muse, mutect2
- UNC13C | c.875G>C p.R292P | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV52843724; called by muse, mutect2
- USP27X | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV71200891; called by muse, mutect2
- WNK4 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1301021422; called by muse, mutect2, varscan2
- ZCCHC13 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767402712; called by muse, mutect2, varscan2
- ZNF727 | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs756279984, COSV70701715; called by muse, mutect2, varscan2
- AGAP3 | c.820G>T p.A274S (on ENST00000622464; = p.A310S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP44 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ARHGEF35 | c.1097A>T p.E366V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ARHGEF6 | c.2241G>T p.R747S | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCDC15 | c.2224A>T p.R742W | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.208); called by muse, mutect2
- CHD7 | c.3568C>T p.L1190F | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTN5 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CSMD3 | c.5066T>A p.F1689Y (on ENST00000297405 / NM_001363185.1; = p.F1585Y on NM_052900.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- CXCR1 | c.307_318del p.W103_G106del | In Frame Del (DEL) | VAF 42/200 reads (21%) | called by mutect2, pindel, varscan2
- DBNDD2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DISP1 | c.788A>G p.K263R | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNM1 | c.1189G>C p.G397R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DUSP10 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DUSP6 | c.286_293del p.V96Rfs*40 | Frame Shift Del (DEL) | VAF 29/198 reads (15%) | called by mutect2, pindel, varscan2
- ESM1 | c.519del p.S174Lfs*3 | Frame Shift Del (DEL) | VAF 47/241 reads (20%) | called by mutect2, pindel, varscan2
- FAM181B | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FANCM | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- FBN2 | c.8568G>T p.L2856F | Missense Mutation (SNP) | VAF 79/332 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FCER1G | c.155A>G p.K52R | Missense Mutation (SNP) | VAF 61/362 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FLNC | c.2472T>A p.N824K | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEPH | c.1663G>A p.G555S (on ENST00000343002; = p.G288S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3B | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- KIAA1586 | c.1754A>T p.D585V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- KIF20B | c.3368A>T p.Q1123L (on ENST00000371728 / NM_001284259.2; = p.Q1083L on NM_016195.4) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- MAGEB1 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MILR1 | c.952T>A p.F318I | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MTSS2 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2
- MYEF2 | c.753A>T p.E251D | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYLIP | c.1249-1G>T p.X417_splice | Splice Site (SNP) | VAF 56/201 reads (28%) | called by muse, mutect2, varscan2
- NDN | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- OR13F1 | c.353T>A p.M118K | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- OR4K15 | c.480G>T p.M160I (on ENST00000305051; = p.M136I on NM_001005486.1) | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- OR6C6 | c.648C>A p.Y216* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- OR8U1 | c.53C>G p.T18R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2
- P2RY4 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- PLEC | c.13909G>C p.G4637R (on ENST00000322810 / NM_201380.4; = p.G4527R on NM_000445.5) | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PNISR | c.1972G>T p.G658C | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- RBMXL3 | c.2096G>A p.S699N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- RC3H1 | c.908G>T p.W303L | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS11 | c.908G>C p.S303T (on ENST00000397770 / NM_183337.3; = p.S282T on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); called by muse, mutect2
- SEPTIN6 | c.1280+1del p.X427_splice | Splice Site (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- SGK1 | c.332C>G p.P111R | Missense Mutation (SNP) | VAF 88/376 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- SI | c.1325C>G p.A442G | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A9 | c.617_618insT p.F207Lfs*37 | Frame Shift Ins (INS) | VAF 19/92 reads (21%) | called by mutect2, pindel, varscan2
- TMEM108 | c.465_469del p.A156Pfs*21 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- UCK1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- WWC3 | c.1450C>G p.L484V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZDHHC23 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- ZNF229 | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 45/176 reads (26%) | called by muse, mutect2, varscan2
- ZNF776 | c.1447T>C p.S483P | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ANKRD50 | c.3570A>G p.S1190= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as rs377605549; called by muse, mutect2, varscan2
- BTN3A2 | c.603A>G p.L201= | Silent (SNP) | VAF 125/447 reads (28%) | catalogued as rs747545997, COSV62687620; called by muse, mutect2, varscan2
- CCDC166 | c.1257C>A p.P419= | Silent (SNP) | VAF 59/101 reads (58%) | catalogued as COSV72638863; called by muse, mutect2, varscan2
- DMD | c.10527C>A p.I3509= | Silent (SNP) | VAF 23/240 reads (10%) | called by mutect2, varscan2
- DSG3 | c.2814G>A p.S938= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as rs777643996, COSV57126101, COSV57126699; called by muse, mutect2, varscan2
- GLB1L3 | c.1200A>C p.V400= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, varscan2
- KAT14 | c.2310A>G p.T770= | Silent (SNP) | VAF 43/318 reads (14%) | called by muse, mutect2, varscan2
- LHX6 | c.420C>T p.A140= (on ENST00000373755 / NM_001242334.2; = p.A169= on NM_014368.5) | Silent (SNP) | VAF 45/165 reads (27%) | called by muse, mutect2, varscan2
- LIG1 | c.2316C>T p.A772= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs754679745, COSV54391241; called by muse, mutect2, varscan2
- LOXHD1 | c.4044G>A p.R1348= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1259605779; called by muse, mutect2, varscan2
- MALRD1 | c.4452A>G p.P1484= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- MINDY4 | c.2214C>T p.C738= | Silent (SNP) | VAF 44/178 reads (25%) | called by muse, mutect2, varscan2
- MYH6 | c.3117C>T p.S1039= | Silent (SNP) | VAF 83/225 reads (37%) | catalogued as rs140314752; called by muse, mutect2, varscan2
- OR10K1 | c.246G>T p.L82= | Silent (SNP) | VAF 129/474 reads (27%) | catalogued as COSV56871491; called by muse, mutect2, varscan2
- PCDH8 | c.2214G>T p.G738= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- PLA2G12B | c.486T>G p.V162= | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- SLC2A3 | c.1410C>T p.H470= | Silent (SNP) | VAF 86/683 reads (13%) | catalogued as rs146012904; called by muse, varscan2
- SLC9A4 | c.837G>A p.L279= | Silent (SNP) | VAF 89/322 reads (28%) | called by muse, mutect2, varscan2
- SLFN14 | c.1830T>A p.I610= | Silent (SNP) | VAF 66/234 reads (28%) | called by muse, mutect2, varscan2
- SOX3 | c.1182C>T p.L394= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- SPPL2C | c.1353C>A p.V451= | Silent (SNP) | VAF 54/275 reads (20%) | called by muse, mutect2, varscan2
- STX5 | c.502C>T p.L168= | Silent (SNP) | VAF 33/254 reads (13%) | called by muse, mutect2, varscan2
- TAS1R1 | c.2163A>T p.T721= | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- TNR | c.447G>T p.S149= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as COSV54895446; called by muse, mutect2, varscan2
- TRAF3 | c.1383C>T p.N461= | Silent (SNP) | VAF 86/274 reads (31%) | catalogued as rs141356642; called by muse, mutect2, varscan2
- WNK1 | c.6042G>A p.P2014= (on ENST00000315939 / NM_018979.4; = p.P1766= on NM_014823.3) | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs923054108; called by muse, mutect2, varscan2
- ZNF417 | c.534C>T p.D178= | Silent (SNP) | VAF 62/338 reads (18%) | catalogued as rs781105441; called by muse, mutect2, varscan2
- ZNF534 | c.393T>C p.T131= (on ENST00000332323 / NM_001143939.3; = p.T118= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- ZNHIT3 | c.81G>T p.V27= | Silent (SNP) | VAF 30/179 reads (17%) | catalogued as rs1406067352; called by muse, mutect2, varscan2
- AFG3L2 | c.*43A>T | 3'UTR (SNP) | VAF 67/244 reads (27%) | called by muse, mutect2, varscan2
- BAIAP2 | chr17:81031171 G>A | 5'Flank (SNP) | VAF 22/318 reads (7%) | catalogued as rs1368872523; called by muse, mutect2
- MEFV | c.1759+25G>A | Intron (SNP) | VAF 124/545 reads (23%) | catalogued as rs777830391; called by muse, mutect2, varscan2
- MOXD1 | c.265-11A>G | Intron (SNP) | VAF 40/174 reads (23%) | called by muse, mutect2, varscan2
- MST1L | n.971C>A | RNA (SNP) | VAF 43/365 reads (12%) | catalogued as rs781068682; called by muse, mutect2, varscan2
- MYCBPAP | c.-76G>T | 5'UTR (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- MYCBPAP | c.-75C>T | 5'UTR (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- NCAN | c.*71C>A | 3'UTR (SNP) | VAF 55/175 reads (31%) | called by muse, mutect2, varscan2
- NCAPG2 | c.*82A>C | 3'UTR (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- NOL4L | chr20:32485765 C>T | 5'Flank (SNP) | VAF 38/176 reads (22%) | called by muse, mutect2, varscan2
- NR2C1 | c.1393+503A>G | Intron (SNP) | VAF 41/207 reads (20%) | called by muse, mutect2, varscan2
- OR5AK4P | n.639G>A | RNA (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- SLC24A1 | c.2883+10C>G | Intron (SNP) | VAF 69/241 reads (29%) | called by muse, mutect2, varscan2
- TERT | c.1573+9G>T | Intron (SNP) | VAF 134/205 reads (65%) | called by muse, mutect2, varscan2
- TSEN34 | c.*333G>A | 3'UTR (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- TUBB7P | n.1196del | RNA (DEL) | VAF 51/235 reads (22%) | called by mutect2, pindel, varscan2
- ZNF496 | c.651+352A>G | Intron (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- ZP4 | c.*15C>T | 3'UTR (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
